Somatic mutation profile of tumor specimen BA2814D (aliquot aq-BA2814D) from BEATAML1.0 case 2539, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with t(9;11)(p22;q23), MLLT3-MLL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.0 years (22,999 days).
Specimen BA2814D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c994431-0294-431f-9730-eb4f1d8aad51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2997D (Solid Tissue Normal), aliquot aq-BA2997D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/28bdd763-9df9-41e1-af93-c456b8874b5c

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC141 | c.1955C>T p.T652I | Missense Mutation (SNP) | VAF 54/95 reads (57%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV99836750; called by muse, mutect2, varscan2
- KLHL32 | c.1120C>G p.R374G | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100987179, COSV65113323; called by muse, mutect2, varscan2
- PXDNL | c.4100C>T p.T1367M | Missense Mutation (SNP) | VAF 104/201 reads (52%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs201574671; called by muse, mutect2, varscan2
- RPTOR | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV60808991; called by muse, mutect2, varscan2
- TMC3 | c.672C>A p.Y224* | Nonsense Mutation (SNP) | VAF 12/24 reads (50%) | catalogued as COSV63923641; called by muse, mutect2, varscan2
- UNC13C | c.6280C>T p.L2094F | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52876513; called by muse, mutect2, varscan2
- USH2A | c.1438G>A p.V480I | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.711); catalogued as rs138694314; ClinVar: uncertain significance; called by muse, mutect2
- ZNF595 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as rs1442639704; called by muse, mutect2
- ZNF880 | c.1216C>A p.Q406K | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs75346003, COSV69905751; called by mutect2, varscan2
- ADGRL3 | c.633C>A p.Y211* (on ENST00000506720 / NM_001322402.2; = p.Y143* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- EIF3A | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2
- FAM186B | c.1439G>T p.W480L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2
- IL1R1 | c.1681C>A p.Q561K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2
- NYAP2 | c.1633C>G p.L545V | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- PLRG1 | c.97G>C p.V33L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO4C1 | c.1397C>A p.T466K | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.017); called by muse, mutect2
- ADCY9 | c.882C>T p.I294= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV53574644; called by muse, mutect2, varscan2
- NBN | c.15G>A p.L5= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs1363180098; called by muse, mutect2, varscan2
- PEG3 | c.93G>A p.P31= | Silent (SNP) | VAF 19/164 reads (12%) | catalogued as rs182961814, COSV55631349; called by muse, mutect2, varscan2
- PPP1R9B | c.258G>T p.A86= | Silent (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- COL6A3 | c.6592-46C>T | Intron (SNP) | VAF 10/34 reads (29%) | catalogued as rs200942887; called by muse, mutect2, varscan2
- ZDHHC23 | c.1041-514C>A | Intron (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
